Somatic mutation profile of tumor specimen TCGA-G7-7502-01A (aliquot TCGA-G7-7502-01A-11D-2201-08) from TCGA case TCGA-G7-7502, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 83.1 years (30,346 days).
Specimen TCGA-G7-7502-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6abbcff0-e273-4ccb-8c05-160ed179f2b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-7502-10A (Blood Derived Normal), aliquot TCGA-G7-7502-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c37c920e-1cd4-483e-a2c9-29a03c0550e1

The open-access MAF lists 66 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 14, Frame Shift Del 6, Splice Site 3, Intron 2, In Frame Ins 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.683C>G p.P228R (on ENST00000219054; = p.P149R on NM_001308169.2) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54584555; called by muse, mutect2, varscan2
- ACY1 | c.922-2A>C p.X308_splice | Splice Site (SNP) | VAF 13/63 reads (21%) | catalogued as COSV68343970; called by muse, mutect2, varscan2
- ADGRA2 | c.1824C>G p.F608L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.664); catalogued as COSV59443367; called by muse, mutect2, varscan2
- APEH | c.2113A>G p.S705G | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV56533615; called by muse, mutect2, varscan2
- BPIFA1 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1047880651, COSV62824469; called by muse, mutect2, varscan2
- CCDC62 | c.1585A>T p.M529L | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53433245; called by muse, mutect2, varscan2
- CDCA8 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV59238753; called by muse, mutect2, varscan2
- COL6A1 | c.3046G>A p.V1016I | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV62613043; called by muse, mutect2, varscan2
- CSF2RB | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV53257461; called by muse, mutect2, varscan2
- DNAH8 | c.11458T>C p.F3820L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59443831; called by muse, mutect2, varscan2
- EHMT2 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV64993818; called by muse, mutect2, varscan2
- GAPVD1 | c.4060G>A p.V1354I (on ENST00000394104; = p.V1363I on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs374403416; called by muse, mutect2, varscan2
- GRB7 | c.34A>G p.S12G | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV58447799; called by muse, mutect2, varscan2
- GUCD1 | c.703T>A p.F235I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV68035104; called by muse, mutect2, varscan2
- HEATR3 | c.400-1G>A p.X134_splice | Splice Site (SNP) | VAF 30/58 reads (52%) | catalogued as rs777147572, COSV53529183; called by muse, mutect2, varscan2
- HYDIN | c.13701A>T p.K4567N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV66638902; called by muse, mutect2, varscan2
- JAGN1 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.054); catalogued as COSV57061930; called by muse, mutect2, varscan2
- KATNIP | c.2725T>A p.S909T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs958010523, COSV55180051; called by muse, mutect2, varscan2
- LRFN4 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV58921463; called by muse, mutect2, varscan2
- LRP5 | c.4127C>T p.P1376L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV53715357; called by muse, mutect2, varscan2
- LRRC40 | c.88G>C p.G30R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV63938701; called by muse, mutect2
- MECR | c.1117A>T p.M373L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV55285355; called by muse, mutect2, varscan2
- MOXD1 | c.414T>G p.D138E | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60944188; called by muse, mutect2, varscan2
- N4BP2 | c.3241del p.S1081Vfs*24 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | catalogued as COSV99788213; called by mutect2, pindel, varscan2
- NEO1 | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV56070925; called by muse, mutect2, varscan2
- NRG1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs78513616, CM133118; called by muse, mutect2, varscan2
- OLAH | c.481G>A p.G161S (on ENST00000378228 / NM_001039702.3; = p.G214S on NM_018324.3) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs764484977, COSV65492319; called by muse, mutect2, varscan2
- OR6K2 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV62743438; called by muse, mutect2, varscan2
- PAPPA2 | c.4676G>T p.G1559V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62797075; called by muse, mutect2, varscan2
- PRAMEF1 | c.1265T>C p.L422S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV60009142; called by muse, mutect2
- RANBP3 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV50381500; called by muse, mutect2, varscan2
- RPH3A | c.511C>A p.P171T (on ENST00000389385 / NM_001143854.2; = p.P167T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66990996; called by muse, mutect2, varscan2
- SCAMP2 | c.517T>A p.W173R | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV51511291; called by muse, mutect2, varscan2
- SEZ6L2 | c.2288A>T p.K763I (on ENST00000308713 / NM_001114099.3; = p.K693I on NM_012410.4) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58099283; called by muse, mutect2, varscan2
- SLC15A4 | c.1451T>C p.M484T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1414766404, COSV57161390; called by muse, mutect2, varscan2
- SLC35B2 | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV51489136; called by muse, mutect2, varscan2
- SLC5A12 | c.657T>G p.N219K | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as COSV54821120; called by muse, mutect2, varscan2
- SLITRK1 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV65675491; called by muse, mutect2, varscan2
- STAB1 | c.5484C>A p.C1828* | Nonsense Mutation (SNP) | VAF 17/152 reads (11%) | catalogued as COSV58733573, COSV58735924; called by muse, mutect2, varscan2
- UBAC2 | c.125T>C p.V42A (on ENST00000403766 / NM_001144072.2; = p.C84R on NM_177967.4) | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV63117949; called by muse, mutect2, varscan2
- ZFP14 | c.1213T>G p.F405V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54202320; called by muse, mutect2, varscan2
- AHNAK | c.8139del p.L2714* | Frame Shift Del (DEL) | VAF 70/260 reads (27%) | called by mutect2, pindel, varscan2
- DAG1 | c.698del p.N233Tfs*34 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- DNMT1 | c.3748del p.S1250Pfs*31 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- KDM3A | c.3541_3542insGGG p.K1180_D1181insG | In Frame Ins (INS) | VAF 45/115 reads (39%) | called by mutect2, pindel, varscan2
- KNL1 | c.1683_1684del p.N561Kfs*2 (on ENST00000346991 / NM_170589.5; = p.N535Kfs*2 on NM_144508.5) | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- MRPL2 | c.519_520+12del p.X173_splice | Splice Site (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- TMED1 | c.388_400delinsC p.D130_V134delinsL | In Frame Del (DEL) | VAF 31/153 reads (20%) | called by pindel, varscan2*
- TRIM48 | c.458G>T p.W153L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2
- ZNF776 | c.747del p.N249Kfs*143 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- BRD2 | c.1248T>C p.A416= | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as rs1020141414, COSV66373237; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1132C>T p.L378= | Silent (SNP) | VAF 12/211 reads (6%) | catalogued as COSV58114933; called by muse, mutect2
- CIR1 | c.657A>G p.K219= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV59596007; called by muse, mutect2
- CSF2RB | c.2595G>T p.V865= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as COSV53257452; called by muse, mutect2, varscan2
- ECEL1 | c.567C>T p.D189= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs770637480, COSV58812146; called by muse, mutect2, varscan2
- FAM162A | c.408C>T p.N136= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV51658102; called by muse, mutect2, varscan2
- HOXA10 | c.1056G>A p.E352= | Silent (SNP) | VAF 74/171 reads (43%) | catalogued as COSV52228784; called by muse, mutect2, varscan2
- KMT2D | c.8067G>C p.L2689= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV56437953; called by muse, mutect2, varscan2
- MYH15 | c.5487C>T p.S1829= | Silent (SNP) | VAF 36/198 reads (18%) | catalogued as COSV56309567; called by muse, mutect2, varscan2
- PER3 | c.231A>C p.L77= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV50012516; called by muse, mutect2, varscan2
- STK36 | c.1869C>G p.L623= | Silent (SNP) | VAF 62/121 reads (51%) | catalogued as COSV55326386; called by muse, mutect2, varscan2
- TUBB1 | c.555G>A p.A185= | Silent (SNP) | VAF 24/181 reads (13%) | catalogued as COSV53885802; called by muse, mutect2, varscan2
- TXLNB | c.1971A>G p.A657= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV64443942; called by muse, mutect2, varscan2
- ZNF101 | c.177G>C p.L59= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100543461, COSV58908900; called by muse, mutect2, varscan2
- MYH7B | c.2100+135A>T | Intron (SNP) | VAF 26/50 reads (52%) | catalogued as COSV99482366; called by muse, mutect2, varscan2
- ZSCAN2 | c.407-4279G>A | Intron (SNP) | VAF 20/60 reads (33%) | catalogued as rs745975368, COSV100509500; called by muse, mutect2, varscan2
